Somatic mutation profile of tumor specimen TCGA-DS-A0VL-01A (aliquot TCGA-DS-A0VL-01A-21D-A10S-08) from TCGA case TCGA-DS-A0VL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G2; Age at diagnosis: 25.1 years (9,186 days).
Specimen TCGA-DS-A0VL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71388f0b-5ca2-473b-a590-a937dc379587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A0VL-10A (Blood Derived Normal), aliquot TCGA-DS-A0VL-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92d9d238-8798-4d23-af1c-8f983ec4ec35

The open-access MAF lists 78 somatic variants for this specimen: 54 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 23, Nonsense Mutation 7, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY10 | c.4189G>C p.E1397Q | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as COSV63242826; called by muse, mutect2, varscan2
- ADGRG6 | c.2932G>T p.G978C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51596555; called by muse, varscan2
- ANKIB1 | c.2870A>G p.D957G | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV56063957; called by muse, mutect2, varscan2
- ARHGEF11 | c.4153C>T p.Q1385* | Nonsense Mutation (SNP) | VAF 17/125 reads (14%) | catalogued as rs1256832154, COSV59356344; called by muse, mutect2, varscan2
- ATOH8 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60401350; called by muse, mutect2, varscan2
- ATP2B4 | c.3082C>G p.Q1028E | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV58180666; called by muse, mutect2, varscan2
- ATP5PB | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV71953299; called by muse, mutect2, varscan2
- CASP8 | c.326C>G p.S109* (on ENST00000432109 / NM_033355.3; = p.S141* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV51845577, COSV51845735; called by muse, mutect2, varscan2
- CASP8 | c.974G>A p.G325D (on ENST00000432109 / NM_033355.3; = p.G342D on NM_001228.4) | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51855197; called by muse, mutect2
- CDH2 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs201148355, COSV52293905; called by muse, mutect2, varscan2
- CHD7 | c.6587C>T p.T2196I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as CX109367, COSV71112814; called by muse, mutect2, varscan2
- CHRNA5 | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.872); catalogued as COSV55139490; called by muse, mutect2, varscan2
- CLMN | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV54181421, COSV54185203; called by muse, mutect2, varscan2
- DERL1 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | catalogued as rs564730174, COSV52364655; called by muse, mutect2, varscan2
- DQX1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV66353439; called by muse, mutect2, varscan2
- EHMT1 | c.1782C>G p.F594L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58378589; called by muse, mutect2
- FAT3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs538781318, COSV53082222, COSV53087184, COSV53104933; called by muse, mutect2
- GOLGB1 | c.5264A>C p.E1755A | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs753772676, COSV61468202; called by muse, mutect2, varscan2
- IQSEC2 | c.2305G>C p.E769Q (on ENST00000642864 / NM_001111125.3; = p.E564Q on NM_015075.2) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV64726913; called by muse, mutect2
- KDM4B | c.2240C>G p.S747C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV50236309; called by muse, mutect2, varscan2
- LNP1 | c.308G>C p.R103T | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV67346360; called by muse, mutect2, varscan2
- LRP11 | c.1056G>C p.K352N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV53334576; called by muse, mutect2, varscan2
- MCM7 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV57997615; called by muse, mutect2, varscan2
- MED1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as rs372091824; called by muse, mutect2, varscan2
- MGAT4C | c.1297G>T p.G433* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV59830838, COSV59835163; called by muse, mutect2, varscan2
- MON2 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54811003; called by muse, mutect2, varscan2
- MUC17 | c.2042C>G p.S681* | Nonsense Mutation (SNP) | VAF 70/466 reads (15%) | catalogued as COSV60295944; called by muse, mutect2, varscan2
- MUC5AC | c.14740C>T p.H4914Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64370070; called by muse, mutect2, varscan2
- NCOA6 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 46/133 reads (35%) | catalogued as COSV62865775; called by muse, mutect2, varscan2
- NLRC5 | c.3024C>G p.H1008Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as COSV52659235; called by muse, mutect2, varscan2
- OR7G1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as COSV53318255; called by muse, mutect2, varscan2
- PCDHA13 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 112/305 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs1303287274, COSV56493290; called by muse, mutect2, varscan2
- PHF21A | c.1033G>A p.E345K (on ENST00000418153 / NM_001101802.3; = p.E346K on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV57657014; called by muse, mutect2
- PNPLA6 | c.3991G>A p.D1331N (on ENST00000414982 / NM_001166111.2; = p.D1283N on NM_006702.5) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs144558473, CM163553; called by muse, mutect2, varscan2
- POLR1A | c.4238C>G p.S1413C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55696012; called by muse, mutect2, varscan2
- RAD54L2 | c.4357G>A p.D1453N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as rs1258691992, COSV56580091; called by muse, mutect2, varscan2
- RELN | c.6004G>A p.E2002K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.867); catalogued as rs1370290671, COSV59019457; called by muse, mutect2, varscan2
- S100A1 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 213/487 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs375726273; called by muse, mutect2, varscan2
- SCN8A | c.2087G>C p.R696T | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV61987091; called by muse, mutect2, varscan2
- SEPHS2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs766949987, COSV72100787; called by muse, mutect2, varscan2
- SPG11 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM111391, COSV55998922; called by muse, mutect2, varscan2
- ST8SIA3 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 9/65 reads (14%) | PolyPhen benign (0); catalogued as COSV60654726; called by muse, mutect2, varscan2
- TAS2R16 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.043); catalogued as rs773598427, COSV50797955; called by muse, mutect2, varscan2
- TGM7 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs776705863, COSV71772822; called by muse, mutect2
- TMEM132B | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.138); catalogued as rs778033275, COSV54748573; called by muse, mutect2, varscan2
- TNRC18 | c.4450C>T p.R1484W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1467625314, COSV68167632; called by muse, mutect2, varscan2
- TUBGCP5 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.39); catalogued as rs750751827; called by muse, mutect2
- TXNRD1 | c.1609G>C p.E537Q (on ENST00000525566 / NM_001093771.3; = p.E439Q on NM_003330.4) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61597226, COSV61600272; called by muse, mutect2
- TYRO3 | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV55485045; called by muse, mutect2, varscan2
- WDR59 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.026); catalogued as COSV50939117; called by muse, mutect2, varscan2
- WNK3 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV63615044; called by muse, varscan2
- WNT10A | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs779978162, COSV51463193; called by muse, mutect2, varscan2
- ZMYM2 | c.2989G>C p.D997H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV67036026; called by muse, mutect2
- TPTE | c.638G>A p.R213K (on ENST00000618007 / NM_199261.4; = p.R195K on NM_199259.4) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ACTN4 | c.2478G>A p.V826= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as COSV53148085; called by muse, mutect2, varscan2
- AHDC1 | c.3453G>A p.Q1151= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV55940671; called by muse, mutect2, varscan2
- APBB2 | c.123C>G p.L41= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV55957415; called by muse, mutect2, varscan2
- C3orf70 | c.726G>A p.V242= | Silent (SNP) | VAF 30/515 reads (6%) | catalogued as COSV58589339; called by muse, mutect2
- DENND2C | c.2151G>A p.P717= (on ENST00000393274 / NM_001256404.2; = p.P660= on NM_198459.4) | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs548792563, COSV67922862; called by muse, mutect2, varscan2
- DESI1 | c.324T>C p.C108= | Silent (SNP) | VAF 35/186 reads (19%) | catalogued as COSV54354890; called by muse, mutect2, varscan2
- ENTR1 | c.369G>A p.S123= (on ENST00000357365 / NM_001039707.2; = p.S100= on NM_006643.4) | Silent (SNP) | VAF 25/176 reads (14%) | catalogued as rs1400437826, COSV53742421; called by muse, mutect2, varscan2
- EXOC3L4 | c.273G>C p.L91= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV66295762; called by muse, mutect2, varscan2
- FAT3 | c.3174T>C p.I1058= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV53144343; called by muse, mutect2, varscan2
- GRIN2A | c.3018G>A p.A1006= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as rs761132463, COSV58037726; called by muse, mutect2, varscan2
- GUF1 | c.1186C>T p.L396= | Silent (SNP) | VAF 50/96 reads (52%) | catalogued as COSV55781654; called by muse, mutect2, varscan2
- IPO13 | c.2691C>T p.F897= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV54837895; called by muse, mutect2, varscan2
- KLK3 | c.183C>T p.L61= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as rs750794289, COSV58101185, COSV58101594; called by muse, mutect2
- MAP3K14 | c.1404C>T p.F468= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1281234590, COSV60924255; called by muse, mutect2, varscan2
- NIBAN1 | c.2028C>G p.L676= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV62286409; called by muse, mutect2
- NMD3 | c.324G>A p.K108= | Silent (SNP) | VAF 11/138 reads (8%) | catalogued as COSV63618946; called by muse, mutect2
- PDE3A | c.537C>T p.G179= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs778995685, COSV62970130; called by muse, mutect2
- SLC32A1 | c.513C>T p.Y171= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs143574180; called by muse, mutect2, varscan2
- TENM4 | c.4762C>T p.L1588= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as rs779352693, COSV53626816; called by muse, mutect2, varscan2
- THAP7 | c.879G>A p.L293= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV53149359; called by muse, mutect2, varscan2
- VDAC3 | c.159A>G p.K53= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV50081886; called by muse, mutect2, varscan2
- WAS | c.1291C>A p.R431= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV64997445; called by muse, mutect2
- ZNF783 | c.114C>T p.S38= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV65186076; called by muse, mutect2
- AP000769.3 | chr11:65501270 ins C | 5'Flank (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
